Somatic mutation profile of tumor specimen TCGA-N8-A4PN-01A (aliquot TCGA-N8-A4PN-01A-11D-A28R-08) from TCGA case TCGA-N8-A4PN, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Age at diagnosis: 68.6 years (25,064 days).
Specimen TCGA-N8-A4PN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9df03d3-3f03-45ce-8b9f-9b96ab5d9521.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N8-A4PN-10A (Blood Derived Normal), aliquot TCGA-N8-A4PN-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc11ba1d-1e65-4fb3-bbd8-55e6c8ff5c49

The open-access MAF lists 53 somatic variants for this specimen: 43 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 9, Nonsense Mutation 3, Frame Shift Ins 1, Splice Region 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1350_1352dup p.H450_E451insD (on ENST00000521381 / NM_181523.3; = p.H180_E181insD on NM_181504.4) | In Frame Ins (INS) | VAF 21/37 reads (57%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 34/113 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 46/53 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTN4 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs771095541; called by muse, mutect2, varscan2
- ADAMTS8 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 68/439 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as rs763820298, COSV57295275, COSV57297829; called by muse, mutect2, varscan2
- CLUL1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as rs527661052, COSV58111689; called by muse, mutect2, varscan2
- COL11A2 | c.4027G>A p.A1343T (on ENST00000341947 / NM_080680.3; = p.A1236T on NM_080679.2) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.045); catalogued as rs759017753, COSV59497650; called by muse, mutect2, varscan2
- COL3A1 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as rs760324242, COSV58584331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.5930G>A p.R1977H | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.196); catalogued as rs182669506, COSV60394232; called by muse, mutect2, varscan2
- CUBN | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as CD127845; called by muse, mutect2
- DCTN1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62619584; called by muse, mutect2, varscan2
- EEF2K | c.1702G>A p.V568M | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs750302565; called by muse, mutect2, varscan2
- ELOA3 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99796089; called by mutect2, varscan2
- FBXW7 | c.1193C>T p.S398F (on ENST00000281708 / NM_001349798.2; = p.S318F on NM_018315.5) | Missense Mutation (SNP) | VAF 67/97 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55915633, COSV55933240; called by muse, mutect2, varscan2
- KDM6A | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV65037130; called by muse, mutect2, varscan2
- RAB38 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); catalogued as rs143951992; called by muse, mutect2, varscan2
- AFDN | c.3320C>G p.S1107C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ANKRD50 | c.2647C>A p.P883T | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- ANXA5 | c.837T>G p.I279M | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- APAF1 | c.2920C>T p.Q974* (on ENST00000551964 / NM_181861.2; = p.Q920* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- ARHGEF3 | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 146/480 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ARPP21 | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CHST3 | c.569A>T p.D190V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP1A1 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- DNM3 | c.475dup p.M159Nfs*22 | Frame Shift Ins (INS) | VAF 19/43 reads (44%) | called by mutect2, pindel, varscan2
- FGFR3 | c.*1329A>T | Splice Region (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- HMGCL | c.119C>G p.P40R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRK2 | c.7462G>A p.E2488K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP2 | c.616A>C p.T206P | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MAP3K19 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- MRPL37 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- MUC16 | c.38702G>T p.G12901V | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR5AS1 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- OTOP1 | c.702C>G p.I234M | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- PGM3 | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHLPP1 | c.3122T>A p.L1041H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RHD | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RYR2 | c.10615G>T p.D3539Y | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- SPATA16 | c.213A>T p.E71D | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- SPTA1 | c.3469A>T p.I1157F | Missense Mutation (SNP) | VAF 93/236 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- TENM2 | c.863C>A p.A288E (on ENST00000518659 / NM_001122679.2; = p.A97E on NM_001080428.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); called by muse, mutect2
- TRPM6 | c.2479T>G p.W827G | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.3038C>T p.T1013I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- HELQ | c.2625C>T p.P875= | Silent (SNP) | VAF 64/108 reads (59%) | catalogued as COSV99787790; called by muse, mutect2, varscan2
- LRRC15 | c.189G>A p.T63= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs370128213; called by muse, mutect2, varscan2
- MAGEB2 | c.201C>A p.T67= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- MCHR1 | c.393C>T p.I131= | Silent (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- NR3C2 | c.1050T>C p.A350= | Silent (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
- PLCD1 | c.1596C>T p.L532= | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as rs1025104058; called by muse, mutect2, varscan2
- PUS7L | c.1830A>G p.V610= | Silent (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- SHANK2 | c.2046G>C p.G682= | Silent (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- SLC10A2 | c.1005G>A p.S335= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs201571450, COSV55358120; called by muse, mutect2, varscan2
- ILF3 | c.*308G>C | 3'UTR (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2
